Somatic mutation profile of tumor specimen MP2PRT-PAUJRD-TMP1-A (aliquot MP2PRT-PAUJRD-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUJRD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,261 days).
Specimen MP2PRT-PAUJRD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5282b3b2-8d7a-4d54-bd4a-33b6229d34f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJRD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJRD-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef2b377c-bcb5-4f84-bce7-ec0622e0dfc2

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Frame Shift Ins 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN9A | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 101/236 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs775461240, COSV57604465; called by muse, mutect2, varscan2
- APBB1 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 163/379 reads (43%) | called by muse, mutect2, varscan2
- CDH7 | c.74G>T p.S25I | Missense Mutation (SNP) | VAF 133/319 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MAGEC3 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- MEF2D | c.270_271insGAAGGAAG p.K91Efs*82 | Frame Shift Ins (INS) | VAF 117/491 reads (24%) | called by mutect2, pindel, varscan2
- NPTXR | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- LTBP3 | c.363C>A p.G121= | Silent (SNP) | VAF 80/415 reads (19%) | called by muse, mutect2, varscan2
